Somatic mutation profile of tumor specimen TARGET-40-0A4I8O-01A (aliquot TARGET-40-0A4I8O-01A-01D) from TARGET case TARGET-40-0A4I8O, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.6 years (6,070 days).
Specimen TARGET-40-0A4I8O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c789899-44b3-4442-8916-aa787df430a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I8O-10A (Blood Derived Normal), aliquot TARGET-40-0A4I8O-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6998902f-5f71-4693-9ff4-cc4a1cb43df8

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 4 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 4, Splice Site 1, RNA 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DDX39B | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as COSV66018836; called by muse, mutect2, varscan2
- FGF6 | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as rs779702937, COSV57403195; called by muse, mutect2, varscan2
- KIF21A | c.2069G>A p.R690Q (on ENST00000361418 / NM_001378440.1; = p.R677Q on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as rs751062866, COSV62778618; called by muse, varscan2
- RNF10 | c.1884G>A p.K628= | Splice Region (SNP) | VAF 7/26 reads (27%) | catalogued as rs769892274; called by muse, mutect2
- CSMD3 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CYP2C9 | c.1149G>T p.K383N | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HEATR1 | c.6079-1G>T p.X2027_splice | Splice Site (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- KIF23 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- MS4A2 | c.32T>G p.L11R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NLRP13 | c.2102A>T p.E701V | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2
- RELB | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- TRIM49B | c.1261A>T p.S421C | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYT1L | c.1692C>T p.N564= | Silent (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- OR3A2 | c.633G>T p.V211= | Silent (SNP) | VAF 42/137 reads (31%) | catalogued as COSV68695381; called by muse, mutect2, varscan2
- UMOD | c.591G>C p.T197= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV56779096; called by muse, varscan2
- UPB1 | c.522G>A p.G174= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs367553466; called by mutect2, varscan2
- AL133216.2 | n.6427C>T | RNA (SNP) | VAF 5/16 reads (31%) | catalogued as rs747329700; called by muse, varscan2
- FAN1 | c.2593-92C>T | Intron (SNP) | VAF 8/28 reads (29%) | catalogued as rs1049568128, COSV62951259; called by muse, mutect2, varscan2
- FYCO1 | c.55+43C>T | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2
- SIRPB2 | c.859+23A>G | Intron (SNP) | VAF 27/104 reads (26%) | catalogued as rs1277524322; called by muse, mutect2, varscan2
- Z83844.2 | c.93-93G>A | Intron (SNP) | VAF 16/23 reads (70%) | called by muse, mutect2, varscan2
